Somatic mutation profile of tumor specimen 0DWNTX from CCDI case PBCPKK, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Ependymoma, NOS; Tissue or organ of origin: Spinal cord; Age at diagnosis: 12.8 years (4,663 days).
Specimen 0DWNTX: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5d1ead75-6338-4a9b-bb8a-fcfad13fdc60.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DWNR8 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ff4a2a19-c5cf-4c96-8cf6-8ca00d3e6d65

The open-access MAF lists 6 somatic variants for this specimen: 4 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4, Intron 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CIDEA | c.104G>A p.R35H | Missense Mutation (SNP) | VAF 56/356 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.812); catalogued as rs765367947; called by muse, mutect2, varscan2
- ZC2HC1A | c.868G>A p.G290R | Missense Mutation (SNP) | VAF 14/295 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.361); catalogued as rs1429447371; called by muse, mutect2
- KMT2C | c.6676A>G p.R2226G | Missense Mutation (SNP) | VAF 27/436 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.915); called by muse, mutect2
- SLC6A15 | c.2024G>A p.S675N | Missense Mutation (SNP) | VAF 25/412 reads (6%) | SIFT tolerated (0.14); PolyPhen benign (0.334); called by muse, mutect2
- LAMA5 | c.9249C>T p.T3083= | Silent (SNP) | VAF 34/543 reads (6%) | catalogued as rs182957711; called by muse, mutect2
- OAZ3 | c.565+73C>T | Intron (SNP) | VAF 4/66 reads (6%) | catalogued as rs1477555664; called by muse, mutect2
